Somatic mutation profile of tumor specimen BA2841D (aliquot aq-BA2841D) from BEATAML1.0 case 2274, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 31.9 years (11,668 days).
Specimen BA2841D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16710799-547e-41da-8baf-624891d0db3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2317D (Solid Tissue Normal), aliquot aq-BA2317D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/502bd064-44a4-4355-8f00-81dd37e56b1b

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, 5'UTR 2, Nonsense Mutation 2, Frame Shift Ins 2, 3'UTR 1, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 20/139 reads (14%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGAP6 | c.550G>A p.G184R (on ENST00000374056 / NM_001365867.1; = p.G207R on NM_001077665.2) | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554864475; called by muse, mutect2, varscan2
- BTN1A1 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs764761095; called by muse, mutect2, varscan2
- CAMKV | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1176759665; called by muse, mutect2, varscan2
- CEBPA | c.941_946dup p.V314_L315dup | In Frame Ins (INS) | VAF 72/222 reads (32%) | catalogued as COSV57195726, COSV57196258, COSV57200649; called by mutect2, varscan2
- KLHL4 | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 81/128 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781018361, COSV64142272; called by muse, varscan2
- MAP2 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 12/96 reads (13%) | catalogued as COSV52280023; called by muse, mutect2, varscan2
- MUC12 | c.10396G>A p.V3466I (on ENST00000379442; = p.V3323I on NM_001164462.1) | Missense Mutation (SNP) | VAF 77/1283 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs764731576, COSV101060569; called by muse, mutect2
- MUC16 | c.40588G>A p.G13530S | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.991); catalogued as rs1419006271, COSV66694629; called by muse, mutect2, varscan2
- PRKAR2B | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55924942; called by muse, mutect2, varscan2
- ROBO2 | c.3883C>T p.R1295W | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as rs996452061; called by muse, mutect2, varscan2
- ZP4 | c.846T>A p.H282Q | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV63911868; called by muse, mutect2, varscan2
- CDH26 | c.1986G>A p.M662I | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- CEBPA | c.138dup p.A47Cfs*61 | Frame Shift Ins (INS) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- CNOT6 | c.360T>G p.F120L | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- DAG1 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RAD21 | c.1599dup p.E534Rfs*3 | Frame Shift Ins (INS) | VAF 32/127 reads (25%) | called by mutect2, pindel, varscan2
- TCTN2 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 112/378 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PPP1R2C | c.528G>A p.T176= | Silent (SNP) | VAF 46/114 reads (40%) | called by mutect2, varscan2
- EYA3 | c.-6G>C | 5'UTR (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- IER3IP1 | c.-27T>G | 5'UTR (SNP) | VAF 42/91 reads (46%) | called by muse, mutect2, varscan2
- TXLNA | c.*482C>A | 3'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
